Gene-level copy-number profile of tumor specimen TCGA-XF-AAN7-01A from TCGA case TCGA-XF-AAN7, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 60.1 years (21,951 days).
Specimen TCGA-XF-AAN7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.8b4080bd-6709-49e2-9f92-b7ae6a80399f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-AAN7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/80ed035b-5043-4645-a9aa-1ce4902452a7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 21; copy number 2: 12,402; copy number 3: 32,836; copy number 4: 9,643; copy number 5: 3,676; copy number 6: 934; copy number 7: 81; copy number 8: 21; copy number 9: 47; copy number 11: 32; copy number 13: 102; copy number 16: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-AAN7-01A-11D-A42D-01): tumor purity 0.87, ploidy 3.08, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 304 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:17,706,257–17,987,635, 5 genes, copy number 7: AL138724.1, RNA5SP204, Y_RNA, KIF13A, AL023807.1.
- chr6:19,323,428–19,839,080, 1 gene, copy number 16 (within-gene range 5–16): LNC-LBCS.
- chr6:19,612,755–21,232,404, 20 genes, copy number 16 (within-gene range 4–16): KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P.
- chr6:23,649,496–23,857,646, 3 genes, copy number 13: AL133270.1, AL139093.1, SPTLC1P2.
- chr6:28,431,930–28,491,661, 5 genes, copy number 8: ZSCAN23, COX11P1, OR2E1P, Z98745.2, Z98745.1.
- chr6:39,553,811–40,587,364, 16 genes, copy number 8 (within-gene range 2–8): E2F4P1, RNU1-54P, DAAM2, AL592158.1, DAAM2-AS1, MOCS1, TUBBP9, FO393411.1, AL139275.2, TDRG1, LINC00951, AL139275.1, LRFN2, RNU6-250P, AL359475.1, AL033380.1.
- chr6:41,033,627–41,097,787, 1 gene, copy number 7 (within-gene range 2–7): OARD1.
- chr6:41,053,304–44,553,281, 145 genes, copy number 7–13 (broad region; genes not listed).
- chr11:32,435,518–32,458,769, 1 gene, copy number 7 (within-gene range 5–7): WT1-AS.
- chr11:32,583,798–35,020,591, 52 genes, copy number 7–11: EIF3M, HNRNPA3P9, CCDC73, AL049714.1, PRRG4, QSER1, Y_RNA, DEPDC7, TCP11L1, PIGCP1, LINC00294, CSTF3, CSTF3-DT, Y_RNA, RPL29P23, Y_RNA, AL136126.1, HIPK3, KIAA1549L, AL137161.1, AL133399.1, AL049629.1, C11orf91, AL049629.2, CD59, FBXO3, FBXO3-DT, AC113192.3, AC113192.2, LINC02722, AC113192.1, LINC02721, LMO2, AC132216.1, AC090469.1, CAPRIN1, NAT10, ABTB2, Y_RNA, MMADHCP2, AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343.
- chr16:8,788,823–9,518,325, 17 genes, copy number 7 (within-gene range 2–7): PMM2, AC012173.1, AC022167.2, CARHSP1, AC022167.1, AC022167.4, LITAFD, USP7, AC022167.3, AC087190.2, C16orf72, AC087190.3, AC087190.1, RPL21P119, LINC02177, AC012178.1, LINC01177.
- chr16:15,931,697–17,470,960, 30 genes, copy number 7–9 (within-gene range 5–9): RPL15P20, ABCC1, RPL17P40, ABCC6, AC136624.1, NOMO3, AC136624.3, AC136624.2, MIR3179-2, MIR3670-2, AC138969.2, MIR3180-2, PKD1P1, Y_RNA, AC138969.1, MIR6511A2, MIR6770-2, AC138969.3, PKD1P2, MIR6511A3, NPIPA7, AC136619.1, AC136431.1, AC136619.2, AC136431.2, AC092326.1, AC098965.1, AC109446.3, TCERG1P2, XYLT1.
- chr16:17,405,678–18,151,595, 8 genes, copy number 7 (within-gene range 3–7): AC009152.6, AC009152.1, AC009152.3, AC109495.1, AC025277.1, RPL7P47, AC010601.1, AC010601.2.

Autosomal genes at a single copy (total copy number 1): 21. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
